Somatic mutation profile of tumor specimen TCGA-86-A456-01A (aliquot TCGA-86-A456-01A-11D-A24D-08) from TCGA case TCGA-86-A456, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 78.1 years (28,533 days).
Specimen TCGA-86-A456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a03f1cb-556e-4051-bfe8-7c2bb4fc2c30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-A456-10A (Blood Derived Normal), aliquot TCGA-86-A456-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/306d2308-a5f0-41a4-81b9-48e037117f23

The open-access MAF lists 374 somatic variants for this specimen: 285 protein-altering or splice-affecting, 80 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 241, Silent 80, Nonsense Mutation 25, Frame Shift Del 7, Splice Site 6, RNA 5, Frame Shift Ins 3, Splice Region 3, Intron 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNNM4 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs1455470131, CM136859, COSV100998630; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.15); catalogued as rs999720158, COSV99771311; called by muse, mutect2, varscan2
- ABCA13 | c.6392A>T p.Q2131L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.146); catalogued as COSV101329963; called by muse, mutect2, varscan2
- ABCA2 | c.3700G>T p.G1234C (on ENST00000614293; = p.G1204C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99687159; called by muse, mutect2
- AC018630.4 | c.208A>G p.R70G | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV99958495; called by muse, mutect2, varscan2
- ADAMTS2 | c.2891C>A p.P964H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52397447; called by muse, mutect2, varscan2
- ADGRV1 | c.4395A>T p.R1465S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.921); catalogued as COSV101315630; called by muse, mutect2
- AFF2 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.739); catalogued as COSV100649409, COSV60666964; called by muse, mutect2, varscan2
- AFF2 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.575); catalogued as COSV100649410; called by muse, mutect2, varscan2
- AIFM1 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780862; called by muse, mutect2, varscan2
- AKAP6 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99799314; called by muse, mutect2
- ALG10 | c.1014G>T p.W338C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56792911, COSV99847976; called by muse, mutect2, varscan2
- ARF3 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV99873038; called by muse, mutect2, varscan2
- ARFGEF1 | c.2104A>G p.I702V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as COSV99141406; called by muse, mutect2, varscan2
- ART1 | c.157T>C p.C53R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99167135; called by muse, mutect2, varscan2
- ATP2B3 | c.3557T>C p.I1186T | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV99683511; called by muse, mutect2, varscan2
- ATXN2L | c.1307C>G p.P436R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100294001, COSV100294310; called by muse, mutect2
- BACE2 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1401344457, COSV100160621, COSV100161077; called by muse, mutect2, varscan2
- BMP10 | c.1214G>C p.G405A | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770327; called by muse, mutect2
- BRINP3 | c.131T>A p.F44Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100818486; called by muse, mutect2, varscan2
- BRWD3 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100955806; called by muse, mutect2, varscan2
- C3orf20 | c.2647G>A p.V883M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.009); catalogued as COSV99513573; called by muse, mutect2, varscan2
- C8orf34 | c.415G>T p.G139* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100445069; called by muse, mutect2, varscan2
- CA10 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.372); catalogued as COSV99562063; called by muse, mutect2, varscan2
- CA3 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99570595; called by muse, mutect2, varscan2
- CACNA1G | c.6952A>T p.S2318C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV100661387; called by muse, mutect2
- CACNB2 | c.766C>A p.P256T (on ENST00000324631 / NM_201596.3; = p.P201T on NM_000724.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99993524; called by muse, mutect2, varscan2
- CADPS2 | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100461427; called by muse, mutect2
- CCDC150 | c.1562A>T p.K521M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99776633; called by muse, mutect2, varscan2
- CCDC42 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV99549722; called by muse, mutect2
- CCDC57 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV101051843; called by muse, mutect2, varscan2
- CCKBR | c.355A>T p.T119S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100582810; called by muse, mutect2, varscan2
- CCR2 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs201184651, COSV99432163; called by muse, mutect2, varscan2
- CD46 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522812; called by muse, mutect2, varscan2
- CDC23 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs756391105, COSV101202983; called by muse, mutect2, varscan2
- CDH12 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.578); catalogued as COSV101201876; called by muse, mutect2
- CELA2B | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV65545579; called by muse, mutect2, varscan2
- CEP112 | c.2766A>T p.E922D (on ENST00000392769 / NM_001353127.1; = p.E178D on NM_001037325.3) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100438976; called by muse, mutect2, varscan2
- CGNL1 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV55575036; called by muse, mutect2, varscan2
- CHMP5 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 5/66 reads (8%) | catalogued as COSV99794523; called by muse, mutect2
- CLEC1A | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.307); catalogued as COSV100191242; called by muse, mutect2, varscan2
- CLRN1 | c.359T>C p.M120T (on ENST00000327047 / NM_174878.3; = p.M44T on NM_052995.2) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs121908141, CM013797, COSV99902368; called by muse, mutect2, varscan2
- CNTNAP3 | c.2163G>T p.K721N | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99904381; called by muse, mutect2, varscan2
- COL4A6 | c.3463C>T p.P1155S | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.437); catalogued as rs1476368971, COSV100563631; called by muse, mutect2
- COL5A1 | c.4231-1G>T p.X1411_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as CS128992; called by muse, mutect2, varscan2
- CPA2 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV99743848; called by muse, mutect2
- CSF2RB | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.496); catalogued as COSV99453406; called by muse, mutect2, varscan2
- CSF3R | c.1301G>T p.R434I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV58966911, COSV58967098; called by muse, mutect2, varscan2
- CSMD1 | c.8626T>A p.F2876I (on ENST00000520002; = p.F2875I on NM_033225.6) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV59374803; called by muse, mutect2
- CSMD3 | c.10015G>T p.G3339C (on ENST00000297405 / NM_001363185.1; = p.G3170C on NM_052900.3) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99828373; called by muse, mutect2, varscan2
- CSMD3 | c.2635G>A p.D879N (on ENST00000297405 / NM_001363185.1; = p.D775N on NM_052900.3) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as COSV52209212, COSV99828376; called by muse, mutect2, varscan2
- CUL7 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs561958734, COSV99538112; called by muse, mutect2
- CWH43 | c.1820A>T p.D607V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99893032; called by muse, mutect2, varscan2
- CXorf65 | c.19C>A p.H7N | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV104370508, COSV99340097; called by muse, mutect2, varscan2
- CXorf66 | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100983852; called by muse, mutect2, varscan2
- DCLK3 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV101373917; called by muse, mutect2, varscan2
- DGKK | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.055); catalogued as rs781952576, COSV101052928; called by muse, mutect2, varscan2
- DIAPH1 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV99526057; called by mutect2, varscan2
- DLGAP1 | c.1585A>T p.S529C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV100228739; called by muse, mutect2
- DMD | c.9167C>T p.S3056F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58957498; called by muse, mutect2, varscan2
- DMD | c.1714A>T p.S572C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV55895598; called by muse, mutect2
- DNAH8 | c.11785A>T p.K3929* | Nonsense Mutation (SNP) | VAF 32/204 reads (16%) | catalogued as COSV100543930; called by muse, mutect2, varscan2
- DNAH9 | c.1998G>T p.W666C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99304823; called by muse, mutect2, varscan2
- DPP3 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as COSV100567773; called by muse, mutect2, varscan2
- DPP8 | c.1013A>G p.N338S (on ENST00000341861 / NM_001320875.2; = p.N322S on NM_017743.6) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100202191; called by muse, mutect2, varscan2
- DSCAM | c.3147C>A p.Y1049* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV101259498; called by muse, mutect2, varscan2
- DTNBP1 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV100160519; called by muse, mutect2, varscan2
- DUSP29 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100633255; called by muse, mutect2, varscan2
- DZIP1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100714031, COSV61270640; called by muse, mutect2
- EPHA6 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101061288; called by muse, mutect2, varscan2
- EPPK1 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101599773; called by muse, mutect2, varscan2
- ERBB2 | c.645G>T p.L215= | Splice Region (SNP) | VAF 19/102 reads (19%) | catalogued as rs1040674885, COSV99507101; called by muse, mutect2, varscan2
- ERBB3 | c.775T>A p.C259S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99916168; called by muse, mutect2, varscan2
- EVI5 | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100789670; called by muse, mutect2, varscan2
- FAM117B | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs1397515258, COSV100287315; called by mutect2, varscan2
- FAM47C | c.2511G>T p.E837D | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV100792380; called by muse, mutect2, varscan2
- FAT3 | c.10834G>A p.D3612N | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99963358; called by muse, mutect2, varscan2
- FBXO7 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.058); catalogued as COSV56682102, COSV99832533; called by muse, mutect2
- FIGNL2 | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV73729264; called by muse, mutect2
- FLNA | c.4154C>A p.T1385K | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.5); catalogued as COSV100774408; called by muse, mutect2, varscan2
- FMNL2 | c.923G>T p.R308M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.471); catalogued as COSV56503907, COSV99979140; called by muse, mutect2, varscan2
- FTSJ3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100037224; called by muse, mutect2
- GFRAL | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100474797, COSV100475014; called by muse, mutect2, varscan2
- GK2 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV100725878; called by muse, mutect2, varscan2
- GLCCI1 | c.966+1G>T p.X322_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99780193; called by muse, mutect2, varscan2
- GLP1R | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as COSV64714717; called by muse, mutect2, varscan2
- GLP1R | c.623C>G p.A208G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV100952498, COSV64716197; called by muse, mutect2, varscan2
- GNAT1 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM1514202, COSV99137265; called by muse, mutect2, varscan2
- GPKOW | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99332534; called by muse, mutect2
- GPR139 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100429705; called by muse, mutect2, varscan2
- GRIA3 | c.2651A>T p.Y884F | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV99989409; called by muse, mutect2, varscan2
- GRIK4 | c.898G>T p.G300W | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101483516; called by muse, mutect2, varscan2
- GRM7 | c.1533G>A p.W511* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100735575, COSV100735952; called by muse, mutect2
- H2AP | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.865); catalogued as COSV100586911; called by muse, mutect2, varscan2
- HAPLN3 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100613651; called by muse, mutect2, varscan2
- HAUS2 | c.518T>A p.M173K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99535322; called by muse, mutect2, varscan2
- HHAT | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99803088; called by muse, mutect2, varscan2
- HS3ST4 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV100500488; called by muse, varscan2
- HUWE1 | c.11101G>T p.G3701C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53363218; called by muse, mutect2
- IFT80 | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV100424543; called by muse, mutect2
- IL11RA | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52405229; called by muse, mutect2
- IL17RA | c.932-1G>C p.X311_splice | Splice Site (SNP) | VAF 13/204 reads (6%) | catalogued as COSV100082940, COSV60056249; called by muse, mutect2
- IL1RAPL1 | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as rs769058210, COSV100145991; called by muse, mutect2, varscan2
- IL9R | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1351664632, COSV99729493; called by muse, mutect2, varscan2
- INPP5D | c.2504C>G p.T835R (on ENST00000445964 / NM_001017915.3; = p.T834R on NM_005541.5) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100856591; called by muse, mutect2, varscan2
- IPO13 | c.1058A>C p.N353T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1344709213, COSV100961080; called by muse, mutect2, varscan2
- IQCN | c.2702G>A p.W901* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV100828205; called by muse, mutect2, varscan2
- IRS4 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV100929475; called by muse, mutect2, varscan2
- KANSL1 | c.2425A>T p.S809C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV99294221; called by muse, mutect2, varscan2
- KCNC4 | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100873587; called by muse, mutect2, varscan2
- KIF21B | c.628T>C p.S210P | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100144027; called by muse, mutect2, varscan2
- KLHL4 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.006); catalogued as COSV100909307; called by muse, mutect2, varscan2
- KRTAP5-5 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV101294158; called by muse, varscan2
- LAMC1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 22/172 reads (13%) | catalogued as COSV99279228; called by muse, mutect2, varscan2
- LARGE1 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100504893; called by muse, mutect2, varscan2
- LDHD | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100096835; called by muse, mutect2, varscan2
- LEPR | c.852T>C p.A284= | Splice Region (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100756410; called by muse, mutect2
- LILRA2 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as COSV52194571; called by muse, mutect2, varscan2
- LPL | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100255418; called by muse, mutect2, varscan2
- LRP12 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770729650, COSV52626697; called by muse, mutect2, varscan2
- LRRC4B | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1185344175, COSV100975866; called by muse, mutect2
- LUC7L3 | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.278); catalogued as COSV99536782; called by muse, mutect2, varscan2
- MACF1 | c.7432G>A p.D2478N | Missense Mutation (SNP) | VAF 6/143 reads (4%) | catalogued as COSV99242423; called by muse, mutect2
- MADD | c.3918G>T p.E1306D | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100211186; called by muse, mutect2, varscan2
- MAGEB4 | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100854628, COSV64397035; called by muse, mutect2, varscan2
- MAGEC1 | c.3346G>A p.A1116T | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99595181; called by muse, mutect2, varscan2
- MALT1 | c.1687C>G p.P563A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100618628; called by muse, mutect2
- MAP1A | c.1544C>A p.P515Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV100288292; called by muse, mutect2, varscan2
- MAS1L | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV101009655; called by muse, mutect2, varscan2
- MASP1 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs372409532, COSV99961986; called by muse, mutect2, varscan2
- MASTL | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100668843; called by muse, mutect2, varscan2
- MBIP | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.947); catalogued as rs967120704, COSV59255794; called by muse, mutect2
- MFHAS1 | c.2936C>T p.T979I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99359326; called by muse, mutect2, varscan2
- MIA2 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99697420; called by muse, mutect2, varscan2
- MRPS6 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as COSV100757818; called by muse, mutect2, varscan2
- MTMR8 | c.1331A>T p.Q444L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100878366; called by muse, mutect2, varscan2
- MUC16 | c.20806T>A p.S6936T | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.028); catalogued as COSV101198804; called by muse, mutect2, varscan2
- MUSK | c.2074C>A p.P692T | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.86); catalogued as COSV51891064, COSV99503835; called by muse, mutect2
- MYBPC3 | c.3656T>A p.L1219Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as CM118274, COSV99920036; called by muse, mutect2, varscan2
- MYO1D | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs755549663, COSV100553758; called by muse, mutect2, varscan2
- MYT1 | c.1972-1G>T p.X658_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100114233; called by muse, mutect2, varscan2
- NANOG | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.437); catalogued as COSV99981466, COSV99981680; called by muse, mutect2, varscan2
- NBEAL2 | c.1810A>T p.T604S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99434986; called by muse, mutect2, varscan2
- NCKAP5 | c.5665G>T p.G1889* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100490692; called by muse, mutect2
- NDNF | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101113115; called by muse, mutect2, varscan2
- NDUFS3 | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99772237; called by muse, mutect2, varscan2
- NFU1 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100361115; called by muse, mutect2
- NLN | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.353); catalogued as COSV101114166; called by muse, mutect2, varscan2
- NLRP12 | c.2752C>A p.L918M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100145004; called by muse, mutect2, varscan2
- NLRP3 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as COSV100275559; called by muse, mutect2, varscan2
- NOS2 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569537; called by muse, mutect2, varscan2
- NPFFR2 | c.397A>G p.N133D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV100440406; called by mutect2, varscan2
- NPHS1 | c.3482-1G>T p.X1161_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100799661; called by muse, mutect2, varscan2
- NPY4R | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV100966135, COSV65399061; called by muse, mutect2, varscan2
- NUP205 | c.5492A>G p.D1831G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1382530475, COSV99606622; called by muse, mutect2, varscan2
- OGA | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100761686; called by muse, mutect2
- OR10J3 | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100171648; called by muse, mutect2, varscan2
- OR14C36 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100507437, COSV58602333; called by muse, mutect2
- OR2T4 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs151201153, COSV63543315; called by muse, varscan2
- OR2T4 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100822418; called by muse, varscan2
- OR2T6 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as rs1424329949, COSV100861500; called by muse, mutect2, varscan2
- OR4N5 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV61320373; called by muse, mutect2, varscan2
- OR52J3 | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100984822; called by muse, mutect2, varscan2
- OR5AC2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs755877682, COSV62279133; called by muse, mutect2, varscan2
- OR6N1 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625113; called by muse, mutect2, varscan2
- OR6N2 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs749301534, COSV100210010; called by muse, mutect2, varscan2
- OR8G5 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as COSV100422292; called by muse, mutect2, varscan2
- OR9G4 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as rs142119383; called by muse, mutect2
- OR9G4 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100265050; called by muse, mutect2, varscan2
- PAPPA2 | c.2761G>T p.D921Y | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV100867698; called by muse, mutect2, varscan2
- PARVG | c.312C>G p.H104Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as rs1408490450, COSV100796034; called by muse, mutect2, varscan2
- PCDH15 | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV100217488, COSV57265915; called by muse, mutect2
- PCDHA1 | c.1251C>A p.S417R | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.067); catalogued as COSV100974311, COSV65375629; called by muse, mutect2, varscan2
- PCDHA3 | c.1645G>T p.V549L | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.275); catalogued as rs782279925, COSV100793243, COSV63542297; called by muse, mutect2
- PCDHB1 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100128072; called by muse, mutect2, varscan2
- PCDHB8 | c.2328G>T p.Q776H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.195); catalogued as COSV99176359; called by muse, mutect2
- PCDHGA4 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99533593; called by muse, mutect2, varscan2
- PDZD2 | c.2389A>G p.I797V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99224253; called by muse, mutect2, varscan2
- PGK2 | c.885C>G p.N295K | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100505370, COSV59164559; called by muse, mutect2, varscan2
- PHF13 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99275532; called by muse, mutect2, varscan2
- PIP4P2 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99575212; called by muse, mutect2, varscan2
- PKHD1 | c.1396G>T p.G466W | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100581852; called by muse, mutect2, varscan2
- PPM1B | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56768053, COSV56770447; called by muse, mutect2, varscan2
- PPP1R3F | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs782132612, COSV99278574; called by muse, mutect2, varscan2
- PRDM16 | c.3250G>T p.E1084* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV54590583; called by muse, mutect2, varscan2
- PRF1 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100942554; called by muse, mutect2, varscan2
- PRKG1 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100907962; called by muse, mutect2, varscan2
- PRODH2 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV99995208; called by muse, mutect2, varscan2
- PSKH2 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99405043; called by muse, mutect2, varscan2
- PTGR2 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966282; called by muse, mutect2, varscan2
- PTPRG | c.2808G>A p.W936* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV55647856; called by muse, mutect2, varscan2
- PTPRM | c.2014G>T p.A672S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59869926; called by muse, mutect2, varscan2
- RANBP2 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 17/258 reads (7%) | catalogued as COSV99311552; called by muse, mutect2
- RB1CC1 | c.2619A>T p.E873D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV99208751; called by muse, mutect2, varscan2
- RBFOX1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs1354114119, COSV60946236; called by muse, mutect2
- RBM14 | c.1423G>T p.G475W | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100036604, COSV59561253; called by muse, mutect2, varscan2
- RBM18 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV101313770; called by muse, mutect2
- RBMX | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV100284631; called by muse, mutect2
- RPL3L | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.025); catalogued as COSV99238082; called by muse, mutect2, varscan2
- RPL8 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV52800293, COSV99068717; called by muse, mutect2
- RYR3 | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101212210; called by muse, mutect2, varscan2
- SAC3D1 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV100100891; called by muse, mutect2, varscan2
- SCN5A | c.4875C>G p.I1625M (on ENST00000333535 / NM_198056.3; = p.I1624M on NM_000335.5) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100347077; called by muse, mutect2, varscan2
- SETBP1 | c.2713A>T p.I905F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV99952464; called by muse, mutect2, varscan2
- SH3TC2 | c.2923C>T p.P975S | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100101396; called by muse, mutect2, varscan2
- SKIV2L | c.3014T>C p.L1005P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100514602; called by muse, mutect2, varscan2
- SLC22A12 | c.1562T>A p.L521* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100327466; called by muse, mutect2, varscan2
- SLC25A13 | c.1999A>T p.T667S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99673221; called by muse, mutect2, varscan2
- SLC26A7 | c.1473G>T p.K491N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.601); catalogued as COSV99402454, COSV99402910; called by muse, mutect2, varscan2
- SLC30A4 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV56005898, COSV99970165; called by muse, mutect2
- SLC30A6 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs756546731, COSV99249463; called by muse, mutect2, varscan2
- SLC6A4 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99911256; called by muse, mutect2, varscan2
- SLCO1C1 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV56870975, COSV99858720; called by muse, mutect2, varscan2
- SLMAP | c.2032A>G p.T678A (on ENST00000428312 / NM_001377924.1; = p.T740A on NM_007159.5) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.273); catalogued as COSV99908225; called by muse, mutect2
- SPAG17 | c.3319+1G>T p.X1107_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100308349; called by muse, mutect2, varscan2
- SPAM1 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99772823; called by muse, mutect2
- SPRR2G | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | PolyPhen benign (0.111); catalogued as COSV100907374; called by muse, mutect2, varscan2
- STAG3 | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1304677852, COSV100425738; called by muse, mutect2
- STK3 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.435); catalogued as rs777502225, COSV101372467; called by muse, mutect2, varscan2
- STOML3 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101105216; called by muse, mutect2, varscan2
- SULT6B1 | c.352C>G p.H118D (on ENST00000535679 / NM_001367551.1; = p.H80D on NM_001032377.2) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99573060; called by muse, mutect2, varscan2
- SUPT6H | c.3540G>T p.Q1180H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV100112207; called by muse, mutect2, varscan2
- TAF1L | c.1365G>T p.W455C | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99644296; called by muse, mutect2, varscan2
- TAF1L | c.1364G>C p.W455S | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99644297; called by muse, mutect2, varscan2
- TAF1L | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV99644299; called by muse, mutect2, varscan2
- TAS2R1 | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV66779726; called by muse, mutect2, varscan2
- TAS2R4 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV56093596; called by muse, mutect2, varscan2
- TBC1D21 | c.552G>T p.W184C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100311233; called by muse, mutect2, varscan2
- TBX22 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100960677; called by muse, mutect2, varscan2
- TEX55 | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99817377, COSV99817404; called by muse, mutect2, varscan2
- TFRC | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV100786409, COSV64053836; called by muse, mutect2, varscan2
- TLE2 | c.833G>T p.S278I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV99504116; called by muse, mutect2
- TLR5 | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | catalogued as COSV100643211; called by muse, mutect2, varscan2
- TNFAIP3 | c.2186G>A p.S729N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV52797207; called by muse, mutect2
- TNR | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.058); catalogued as COSV99688348; called by muse, mutect2, varscan2
- TOM1L1 | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100779154; called by muse, mutect2, varscan2
- TRAPPC8 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99350735; called by muse, mutect2, varscan2
- TRIOBP | c.1702A>T p.N568Y | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.108); catalogued as COSV100730734; called by muse, varscan2
- TRPS1 | c.3634G>A p.E1212K (on ENST00000220888 / NM_001330599.2; = p.E1225K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99629255; called by muse, mutect2, varscan2
- TSHZ2 | c.2927C>A p.S976* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100295584; called by muse, mutect2, varscan2
- TSHZ3 | c.149A>T p.K50M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99550965; called by mutect2, varscan2
- TTN | c.40247C>A p.P13416H (on ENST00000591111; = p.P5992H on NM_003319.4) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | PolyPhen probably damaging (0.961); catalogued as COSV100600565; called by muse, mutect2, varscan2
- TUBA3C | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV101262762; called by muse, mutect2, varscan2
- UBE2I | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100171343; called by muse, mutect2, varscan2
- UGT3A2 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.424); catalogued as COSV99236102; called by muse, mutect2, varscan2
- USH2A | c.1547G>C p.G516A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as CM044734, COSV100231290; called by muse, mutect2, varscan2
- VCAN | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99425072; called by muse, mutect2, varscan2
- WDR47 | c.2687G>T p.W896L (on ENST00000369962 / NM_001142551.2; = p.W897L on NM_014969.5) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728268; called by muse, mutect2, varscan2
- XIRP2 | c.1865T>C p.M622T (on ENST00000628543; = p.M797T on NM_152381.6) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs745638377, COSV54682554, COSV54709863; called by muse, mutect2, varscan2
- XRN1 | c.2217G>T p.L739F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99377494; called by muse, mutect2, varscan2
- YAP1 | c.984+8C>T | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99176057; called by muse, mutect2, varscan2
- YLPM1 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53112420; called by muse, mutect2
- ZACN | c.1073C>G p.S358* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV58038536, COSV99045807; called by muse, mutect2, varscan2
- ZBTB22 | c.1831A>G p.S611G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV99801685; called by muse, mutect2, varscan2
- ZC3H6 | c.3326G>T p.G1109V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100674415; called by muse, mutect2, varscan2
- ZEB1 | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV100313870; called by muse, mutect2, varscan2
- ZNF250 | c.929C>A p.P310Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99480731; called by muse, mutect2, varscan2
- ZNF518A | c.676A>T p.I226F | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100283404; called by muse, mutect2, varscan2
- ZNF532 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100266160; called by muse, mutect2
- ZNF536 | c.3649C>A p.P1217T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100834881, COSV100835340; called by muse, mutect2, varscan2
- ZNF563 | c.1109G>C p.C370S | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99536462; called by muse, mutect2, varscan2
- ZNF577 | c.901A>T p.S301C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100030890, COSV56815243; called by muse, mutect2, varscan2
- ZNF624 | c.1444A>G p.R482G | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.33); catalogued as COSV100257116; called by muse, mutect2, varscan2
- ZNF681 | c.935A>G p.Y312C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101267415; called by muse, mutect2, varscan2
- ZNF711 | c.1415A>T p.E472V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV99340774; called by muse, mutect2
- ZNF774 | c.769_770insT p.H257Lfs*38 | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | catalogued as COSV100586250; called by mutect2, pindel, varscan2
- ZNF808 | c.2383G>T p.V795F | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100707840; called by muse, mutect2, varscan2
- ZSCAN9 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1198626355, COSV52850683; called by muse, mutect2
- ADGRV1 | c.8851A>G p.I2951V | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.257); called by muse, mutect2
- CD44 | c.587del p.Y196Sfs*29 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel
- HMGCLL1 | c.766_794del p.P256Cfs*16 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- HNF4G | c.13_14del p.D5Qfs*25 (on ENST00000354370 / NM_001330561.2; = p.D52Qfs*25 on NM_004133.5) | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- IGHA1 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- IGKV1-8 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGLV7-43 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- MRC1 | c.821C>A p.T274N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MROH7 | c.488dup p.L163Ffs*10 | Frame Shift Ins (INS) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- PCF11 | c.2393T>A p.M798K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRAMEF17 | c.10del p.Q4Sfs*15 | Frame Shift Del (DEL) | VAF 34/231 reads (15%) | called by mutect2, pindel, varscan2
- SCML2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- SUPT6H | c.424_455del p.K142Wfs*24 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- UNC13A | c.3415_3416insG p.P1139Rfs*2 | Frame Shift Ins (INS) | VAF 7/50 reads (14%) | called by mutect2, pindel*, varscan2
- VMO1 | c.390del p.T131Rfs*27 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- ZNF800 | c.1650del p.I552* | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- ACTN2 | c.2511C>A p.I837= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100856635; called by muse, mutect2, varscan2
- AMER1 | c.1980C>A p.G660= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100365581; called by muse, mutect2, varscan2
- ATG10 | c.360G>C p.G120= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV56424859; called by muse, mutect2, varscan2
- ATP1B4 | c.153G>C p.S51= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV54313477, COSV99486228; called by muse, mutect2, varscan2
- C1orf50 | c.228C>T p.N76= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100998089; called by muse, mutect2, varscan2
- CAPSL | c.222C>A p.V74= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs763014353, COSV101274216, COSV68439499; called by mutect2, varscan2
- CELF3 | c.334C>A p.R112= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as COSV99310121; called by muse, mutect2, varscan2
- CHL1 | c.1515C>A p.V505= (on ENST00000397491 / NM_001253387.1; = p.V521= on NM_006614.4) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV56598221, COSV99850483; called by muse, mutect2, varscan2
- CLCC1 | c.1344A>G p.P448= (on ENST00000356970 / NM_001377464.1; = p.P398= on NM_015127.5) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100206313; called by muse, mutect2, varscan2
- CRYGD | c.510C>A p.V170= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100006004; called by muse, mutect2, varscan2
- DAB1 | c.702G>T p.V234= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100139699; called by muse, mutect2
- DBNL | c.483G>A p.V161= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV99803567; called by muse, mutect2
- DCAF12L1 | c.357G>T p.T119= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV100948153, COSV64421813; called by muse, mutect2
- DISP3 | c.1299G>T p.L433= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99607767; called by muse, mutect2
- DMD | c.7893C>A p.R2631= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV100626352, COSV58934994; called by muse, mutect2, varscan2
- DPY19L4 | c.594G>T p.A198= | Silent (SNP) | VAF 33/230 reads (14%) | catalogued as COSV101363165, COSV68962341; called by muse, mutect2, varscan2
- DST | c.20331G>T p.R6777= (on ENST00000361203 / NM_001374722.1; = p.R4474= on NM_015548.5) | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV99752777; called by muse, mutect2, varscan2
- DUSP21 | c.150C>A p.A50= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV100173532, COSV100173656; called by muse, mutect2, varscan2
- FLNC | c.5823C>A p.P1941= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100367775; called by mutect2, varscan2
- FMO1 | c.1341C>A p.P447= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV100707711, COSV61447833; called by muse, mutect2, varscan2
- FOXL2 | c.309C>A p.R103= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100374418; called by muse, mutect2, varscan2
- FSCN3 | c.474G>C p.R158= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99133655; called by muse, mutect2, varscan2
- GAGE1 | c.354C>A p.A118= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- GPR141 | c.324G>T p.V108= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV100550255, COSV57734180; called by muse, mutect2, varscan2
- GRM8 | c.2568C>T p.F856= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV100281517, COSV58799350; called by muse, mutect2
- H2AP | c.216C>T p.A72= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100586909, COSV100586913; called by muse, mutect2, varscan2
- HRNR | c.2088C>T p.G696= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as COSV100913121; called by muse, mutect2, varscan2
- IGHA2 | c.603A>T p.P201= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- IRS4 | c.1497G>T p.R499= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV100929477; called by muse, mutect2
- KCNB2 | c.66A>G p.P22= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV101578701; called by muse, mutect2, varscan2
- KCNH1 | c.1230C>A p.T410= (on ENST00000271751 / NM_172362.3; = p.T383= on NM_002238.4) | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV99658035; called by muse, mutect2, varscan2
- KCTD15 | c.678G>T p.R226= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs747020512, COSV99393083; called by muse, mutect2
- KRTAP4-1 | c.417C>A p.P139= (on ENST00000398472; = p.P120= on NM_033060.3) | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV100893443; called by muse, mutect2, varscan2
- L1CAM | c.2088C>A p.G696= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as COSV100648925; called by muse, mutect2
- LCE1A | c.171G>T p.G57= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100632048, COSV58727647; called by muse, mutect2, varscan2
- LGALS12 | c.681T>C p.H227= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs768343823, COSV99736910; called by muse, mutect2, varscan2
- LHX8 | c.837C>G p.R279= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV99633300; called by muse, mutect2
- LRPAP1 | c.321G>A p.K107= | Silent (SNP) | VAF 52/317 reads (16%) | catalogued as COSV99578837; called by muse, mutect2, varscan2
- MAGEC1 | c.2328G>A p.Q776= | Silent (SNP) | VAF 25/277 reads (9%) | catalogued as COSV99595179; called by muse, mutect2
- MCOLN2 | c.1284T>C p.Y428= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99393673; called by muse, mutect2, varscan2
- MKI67 | c.5478C>T p.A1826= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as COSV100896322; called by muse, mutect2, varscan2
- MRTFB | c.2583A>T p.P861= (on ENST00000571589 / NM_001365412.2; = p.P811= on NM_014048.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV100370968; called by muse, mutect2, varscan2
- MST1 | c.312G>T p.T104= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV56535268, COSV99610617; called by muse, mutect2, varscan2
- NEBL | c.288G>A p.R96= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV101012236; called by muse, mutect2, varscan2
- NLGN4X | c.1560C>T p.S520= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs371904473, COSV52018343, COSV52028153; called by muse, mutect2, varscan2
- NOMO1 | c.3117G>A p.G1039= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs1463661644, COSV99814288; called by muse, mutect2
- NRROS | c.786G>T p.L262= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100145399; called by muse, mutect2, varscan2
- NUP210L | c.1746A>T p.A582= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV99667507; called by muse, mutect2, varscan2
- NXF3 | c.378G>A p.E126= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV101221900; called by muse, mutect2, varscan2
- PASK | c.1725G>T p.R575= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99298926; called by muse, mutect2, varscan2
- PLXND1 | c.4299G>A p.Q1433= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100139235; called by muse, mutect2
- PPT2 | c.147G>T p.S49= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1177800328, COSV99278279; called by muse, mutect2
- PRSS36 | c.369C>A p.A123= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs779381435, COSV99191239; called by muse, mutect2, varscan2
- PSD2 | c.2229C>T p.L743= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99217067; called by muse, mutect2, varscan2
- PTPRH | c.1167G>T p.V389= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99670824; called by muse, mutect2, varscan2
- RBP4 | c.411C>A p.S137= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV101012240; called by muse, mutect2, varscan2
- RCBTB2 | c.309C>T p.L103= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs139359675; called by muse, mutect2
- RELN | c.1587T>C p.P529= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV100632866; called by muse, mutect2, varscan2
- RRAGC | c.474C>T p.H158= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100883810; called by muse, mutect2, varscan2
- SAGE1 | c.2646C>A p.L882= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- SCN11A | c.3471G>A p.A1157= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs771153034, COSV100181135; ClinVar: likely benign; called by muse, mutect2, varscan2
- SGIP1 | c.960G>T p.P320= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as COSV99390868; called by muse, mutect2, varscan2
- SIM1 | c.2235G>C p.L745= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV99492115; called by muse, mutect2, varscan2
- SLC2A12 | c.1710G>A p.V570= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV51601251; called by muse, mutect2
- SLC30A9 | c.783C>T p.T261= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs145726400; called by muse, mutect2, varscan2
- SLC5A1 | c.438C>T p.S146= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99833264; called by muse, mutect2
- SLC8A1 | c.369C>A p.T123= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV100245176; called by muse, mutect2
- SPATA31A1 | c.645C>A p.A215= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2, varscan2
- SUPT20HL1 | c.243A>G p.L81= | Silent (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2, varscan2
- SVIL | c.2076G>C p.L692= (on ENST00000355867 / NM_021738.3; = p.L298= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as COSV100881094; called by muse, mutect2
- TEX11 | c.1371C>G p.T457= (on ENST00000344304; = p.T442= on NM_031276.3) | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100721303, COSV100721455; called by muse, mutect2, varscan2
- TMEM132D | c.1182A>T p.P394= | Silent (SNP) | VAF 54/183 reads (30%) | catalogued as rs1253987585, COSV101396888; called by muse, mutect2, varscan2
- TMEM174 | c.480G>T p.V160= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99703739; called by muse, mutect2
- TSC22D4 | c.216C>T p.F72= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1273679524, COSV100278837; called by muse, mutect2
- TSPAN8 | c.177G>A p.L59= | Silent (SNP) | VAF 9/182 reads (5%) | catalogued as COSV99922478; called by muse, mutect2
- USP9X | c.2808G>T p.V936= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100198700; called by muse, mutect2, varscan2
- USP9X | c.5736T>C p.D1912= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs755940108, COSV100198705; called by muse, mutect2, varscan2
- ZMYM1 | c.141G>T p.L47= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100720922; called by muse, varscan2
- ZNF365 | c.528T>C p.I176= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV101237945; called by muse, mutect2, varscan2
- ZNF532 | c.276G>T p.G92= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100266157; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83096G>T | Intron (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- DNAH8 | chr6:38723035 G>A | 5'Flank (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100543926; called by muse, mutect2, varscan2
- EI24P4 | n.995G>C | RNA (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- GLRXP3 | n.168G>C | RNA (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- MIR498 | n.80C>T | RNA (SNP) | VAF 18/87 reads (21%) | catalogued as rs1277853372; called by muse, mutect2, varscan2
- MIR509-3 | n.53C>A | RNA (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- NACA | c.71-1445C>G | Intron (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100771166; called by muse, mutect2, varscan2
- USH1C | c.1285-3869C>A | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99139360, COSV99139531; called by muse, mutect2
- WASF4P | n.943G>A | RNA (SNP) | VAF 6/36 reads (17%) | catalogued as rs371230257; called by muse, mutect2
